Somatic mutation profile of tumor specimen TCGA-JY-A6FA-01A (aliquot TCGA-JY-A6FA-01A-11D-A33E-09) from TCGA case TCGA-JY-A6FA, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 52.0 years (18,978 days).
Specimen TCGA-JY-A6FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e24fedb2-dac5-4783-8fbd-fc47c5f0ee6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6FA-10A (Blood Derived Normal), aliquot TCGA-JY-A6FA-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/919ed7f3-0975-4cbb-aab0-cde69cd0b9b3

The open-access MAF lists 130 somatic variants for this specimen: 97 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 29, Nonsense Mutation 7, Frame Shift Ins 4, Frame Shift Del 3, 3'UTR 1, 3'Flank 1, In Frame Del 1, 5'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 75/183 reads (41%) | catalogued as rs397508009, CM1110640, COSV101204561; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 100/122 reads (82%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.3161G>A p.R1054K (on ENST00000611781; = p.R998K on NM_052997.2) | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1367819680; called by muse, mutect2, varscan2
- BCKDHB | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1479145876; called by muse, mutect2, varscan2
- CARD11 | c.1663dup p.R555Pfs*38 | Frame Shift Ins (INS) | VAF 20/132 reads (15%) | catalogued as rs762770988; called by mutect2, varscan2
- CHRNA2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368791756, COSV53556413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL18A1 | c.2302C>T p.R768W (on ENST00000359759 / NM_130444.3; = p.R533W on NM_030582.4) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs369114408; called by muse, mutect2, varscan2
- CTDP1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50006281; called by muse, mutect2, varscan2
- DUOX2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1356516454; called by muse, varscan2
- ENTR1 | c.1115G>A p.G372D (on ENST00000357365 / NM_001039707.2; = p.G349D on NM_006643.4) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs762736506, COSV53742519; called by muse, mutect2, varscan2
- FAM170A | c.812T>C p.M271T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs528739250; called by muse, mutect2, varscan2
- FFAR3 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs763567775; called by muse, mutect2, varscan2
- FOXG1 | c.730C>A p.R244S | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111914, COSV57398832; called by muse, mutect2, varscan2
- GABRA1 | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs797045590; ClinVar: uncertain significance; called by muse, mutect2
- GLRX3 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV58693306; called by muse, mutect2, varscan2
- GRID2 | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56185450, COSV56283061; called by muse, mutect2, varscan2
- H2AC13 | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV100704420, COSV100704432; called by muse, mutect2, varscan2
- HNF1A | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | catalogued as COSV57468413; called by muse, mutect2, varscan2
- IRAK3 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs1429189828; called by muse, mutect2, varscan2
- KIF1A | c.3484C>A p.P1162T | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241107; called by muse, mutect2, varscan2
- KLHL40 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs763489381; called by muse, mutect2, varscan2
- KMT2B | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747570960; called by muse, mutect2, varscan2
- LAMP3 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs114675283; called by muse, mutect2, varscan2
- NBN | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619003; called by muse, mutect2
- NLRP4 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV56714505; called by muse, mutect2, varscan2
- NLRP8 | c.1897G>T p.V633F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs768363645, COSV99404545; called by muse, mutect2
- NOTCH3 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54625552; called by muse, mutect2, varscan2
- NYAP2 | c.1357A>G p.R453G | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56009035; called by muse, mutect2
- OR13A1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756684773, COSV100981089; called by muse, mutect2, varscan2
- OR8H1 | c.488G>C p.S163T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV57294402; called by muse, mutect2, varscan2
- PENK | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs944467038; called by muse, mutect2, varscan2
- PLP2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 69/94 reads (73%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1176060696; called by muse, mutect2, varscan2
- QSOX2 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757462508, COSV62395190; called by mutect2, varscan2
- RSPH6A | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs145529811; called by muse, mutect2, varscan2
- SHROOM3 | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs761894567; called by muse, mutect2, varscan2
- STKLD1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs782474036, COSV64311694; called by muse, mutect2, varscan2
- STXBP3 | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1398912005; called by muse, mutect2
- TUBGCP5 | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs549962518; called by muse, mutect2, varscan2
- WT1 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV60066237; called by muse, mutect2, varscan2
- ZBP1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs762891234; called by muse, mutect2, varscan2
- ABCB5 | c.2382G>C p.L794F (on ENST00000404938 / NM_001163941.2; = p.L349F on NM_178559.6) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACKR1 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ACKR1 | c.1002C>A p.S334R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ACTN2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADAMTS14 | c.3244_3252del p.I1082_G1084del | In Frame Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- ALKBH2 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT tolerated (0.17); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ANKH | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARID1A | c.2373C>A p.N791K | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARID4A | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- BEX1 | c.353A>C p.H118P | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CABS1 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CAD | c.4282A>G p.I1428V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CCDC106 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CLIP1 | c.3873G>T p.E1291D (on ENST00000620786 / NM_001247997.1; = p.E1280D on NM_002956.2) | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLTC | c.3193T>C p.F1065L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- COL11A1 | c.4679G>T p.G1560V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DDX5 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- EFEMP1 | c.1210A>T p.R404W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELP4 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- FAM217A | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCGBP | c.9043C>T p.L3015F | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FER1L6 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRY | c.7866del p.E2622Dfs*10 | Frame Shift Del (DEL) | VAF 49/128 reads (38%) | called by mutect2, pindel, varscan2
- GRM1 | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HECTD4 | c.3029T>C p.L1010S | Missense Mutation (SNP) | VAF 61/73 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL10 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAL | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- ITGB3 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ITIH5 | c.2056G>T p.V686L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM1A | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL6 | c.1683C>G p.Y561* | Nonsense Mutation (SNP) | VAF 61/199 reads (31%) | called by muse, mutect2, varscan2
- KRIT1 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MDN1 | c.13001del p.L4334Rfs*14 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- MED10 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NAALADL2 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- NELL1 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NF1 | c.7076T>C p.V2359A (on ENST00000358273 / NM_001042492.3; = p.V2338A on NM_000267.3) | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PDE2A | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RASIP1 | c.2267A>G p.E756G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- RASSF5 | c.1109dup p.D370Efs*7 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- RHO | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RIPOR1 | c.2327dup p.M776Ifs*32 (on ENST00000379312 / NM_001193522.2; = p.M772Ifs*32 on NM_024519.4) | Frame Shift Ins (INS) | VAF 35/99 reads (35%) | called by mutect2, pindel, varscan2
- SALL3 | c.168C>G p.C56W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SECISBP2L | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLITRK3 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SOHLH2 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SSH2 | c.4039G>C p.A1347P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- STRIP1 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- TBCD | c.1542C>A p.F514L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TNN | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRPM1 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TSC1 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUFM | c.1015del p.R339Gfs*46 | Frame Shift Del (DEL) | VAF 57/190 reads (30%) | called by mutect2, pindel, varscan2
- WDFY3 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YEATS2 | c.1266dup p.G423Wfs*22 | Frame Shift Ins (INS) | VAF 20/144 reads (14%) | called by mutect2, pindel, varscan2
- ZNF140 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF804A | c.2931G>C p.E977D | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ADGRL2 | c.1983C>G p.V661= (on ENST00000370717 / NM_001366005.1; = p.V648= on NM_012302.4) | Silent (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1419C>G p.L473= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs761916821, COSV52719389, COSV52722315; called by muse, mutect2, varscan2
- AURKC | c.486G>A p.V162= (on ENST00000302804 / NM_001015878.2; = p.V128= on NM_003160.3) | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- BRD9 | c.1266G>A p.A422= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs145445077, COSV100057226; called by muse, varscan2
- CD7 | c.522A>G p.P174= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs878861746, COSV53938736; called by muse, varscan2
- CDH23 | c.1500T>C p.S500= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- CEND1 | c.216C>T p.L72= | Silent (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- CYP2B6 | c.312C>T p.V104= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs1348111588; called by muse, mutect2, varscan2
- DLGAP2 | c.963C>T p.G321= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs758466387; called by muse, mutect2, varscan2
- DNMT1 | c.2991A>G p.K997= | Silent (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- ENPP3 | c.2217A>G p.E739= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs769019983; called by muse, mutect2, varscan2
- GRAMD1B | c.1416G>T p.V472= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- HNF1A | c.936C>G p.L312= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- JSRP1 | c.144C>T p.P48= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs775914552; called by muse, mutect2, varscan2
- KL | c.1938A>C p.G646= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- MACF1 | c.11706G>A p.E3902= (on ENST00000372915; = p.E1835= on NM_012090.5) | Silent (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- NEBL | c.2682A>T p.G894= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs1334949712; called by muse, mutect2, varscan2
- NOS1 | c.1452C>T p.L484= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs1342786525, COSV57612790; called by muse, mutect2, varscan2
- OR10Z1 | c.135T>A p.I45= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- P2RX5 | c.841C>T p.L281= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV56593379; called by muse, mutect2, varscan2
- PIK3R2 | c.1266C>G p.L422= | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- PRDM1 | c.1443G>A p.P481= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs777578275; called by muse, mutect2, varscan2
- SLC39A8 | c.1266G>A p.K422= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV63222262; called by muse, mutect2, varscan2
- TLE2 | c.252G>C p.L84= | Silent (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- TNRC18 | c.2907G>T p.G969= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- TULP4 | c.58C>T p.L20= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- UCHL3 | c.663A>G p.R221= | Silent (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- USH2A | c.7509C>T p.Y2503= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100245290; called by muse, mutect2, varscan2
- ZNF516 | c.165G>A p.K55= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516644 G>C | 3'Flank (SNP) | VAF 35/46 reads (76%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457874 T>C | 5'Flank (SNP) | VAF 78/275 reads (28%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-367_-117-362del | Intron (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- SLC17A2 | c.*55C>T | 3'UTR (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99613956; called by muse, mutect2, varscan2
